Surgical pathology report (de-identified scan), TCGA case TCGA-29-1778, project TCGA-OV (Ovarian Serous Cystadenocarcinoma), tissue source site Duke, specimen TCGA-29-1778-01A (Primary Tumor).

[page 1 of 4]
TCGA-29-1778

Surg Path

CLINICAL HISTORY:

Abdominal swelling, per E-browser ovarian mass.

GROSS EXAMINATION:

A. "Right ovary and tube (AF1), received fresh for frozen section is a 352 gm, 13 x 6.9 x 6.5 cm right ovary with attached 8.9 x 2 x 1.9 cm fallopian tube. The ovary has an intact smooth tan-pink capsule, and upon section the ovarian parenchyma is completely obliterated by a brown-tan bulging mildly friable mass, and no normal ovarian parenchyma is identified. Adjacent to the ovary is a purple-tan fallopian tube with a 0.1 cm diameter lumen with tan-white mucosa. The fimbriated ends of the fallopian tube is distended by a 4 x 3 x 2 cm smooth encapsulated mass with a cut surface resembling the ovarian mass (tan-white mildly friable and bulging) and notable for hemorrhage. A section of the ovarian tumor is frozen as AF1. No mass lesions are identified, and representative sections are submitted as follows:

- A1- AF1-representative ovarian mass
- A2-A4 representative ovarian mass
- A5- fallopian tube
- A6-A7 fallopian tube mass

B. "Right round ligament", received fresh and placed in formalin is a 2.3 x 1.7 x 0.8 cm fragment of purple-pink fibroadipose tissue. Sections demonstrate pink-tan cut surface with central hemorrhage, and representative sections are submitted in block B1.

C. "Left tube and ovary", received fresh and placed in formalin is a 6.5 gm (fixed weight), 2.5 x 1 x 0.8 cm purple-pink smooth cerebriiformed ovary with adjacent 4 cm long x 0.5 cm diameter fimbriated fallopian tube. The ovarian cut surface is slightly hemorrhagic and grossly unremarkable. The fallopian tube serosa is purple-pink smooth glistening, and the cut surface reveals a pinpoint lumen and tan-white mucosa. There are two paratubal cysts with greatest dimensions of 0.8 cm and 0.4 cm. NO mass lesions are identified, a representative section of ovary submitted in block C1, and fallopian tube with cysts in block C2.

D. "Cervix and uterus and posterior vaginal perineum", received fresh and placed in formalin is a 105 gm, 9 x 5 x 3.5 cm hysterectomy specimen which is opened on the left side per surgeon. On right side adjacent to the endocervical canal is a 2.5 x 2.5 x 2 cm mass. The cut surface is mass is tan-white firm and focally hemorrhagic with infiltrating borders which extend through the serosa to involve the outer one third of myometrium. The mass is 0.6 cm from the vaginal cuff, 2.5 cm from the cervical, and 1.3 cm from the endocervical canal.

The serosa is smooth pink and glistening with a 0.4 cm subserosal nodule on the anterior aspect. The cervix is 3.5 cm in diameter, which has an erythematous anterior aspect, surrounded by a 0.5 cm thick vaginal cuff, and has a 0.2 cm diameter probe patent cervical os leading into a 3 cm long endocervical canal. The 4.5 x 1.5 cm endometrial cavity is lined by a 0.2 cm thick endometrium overlying a 1.4 cm thick myometrium which contains several intramural nodules ranging in size from 0.3 cm to 0.9 cm in greatest dimension. These nodules all have a white whorled bulging cut surface with no necrosis or hemorrhage. No other mass lesions are identified, and representative sections are submitted as follows:

- 1- mass with respect to vaginal cuff and exocervix
- 1- mass with respect to endocervical canal

[page 2 of 4]
TCGA-29-1778

- D3- mass with respect to cervix
- D4- representative mass
- D5- anterior cervix
- D6- left posterior cervix
- D7- anterior myometrium, full-thickness
- D8- posterior myometrium, full-thickness
- D9- subserosal nodules
- D10-D11 intramural nodules

E. "Posterior vaginal peritoneum", received fresh and placed in formalin is a 1.1 x 1 x 0.3 cm fragment of red-brown soft tissue which is grossly and unremarkable and submitted in toto in block E1.

F. "Right IP ligament", received fresh and placed in formalin is a 2.5 x 1.8 x 0.9 cm fragment of pink-yellow fibroadipose tissue. Sections demonstrate an unremarkable fatty cut surface, and representative sections are submitted in block F1.

G. "Right pelvic lymph node", received fresh and placed in formalin is a 6 x 5.5 x 2 cm aggregate of pink-yellow fibroadipose tissue, which is dissected for lymph node candidates. Six lymph node candidates are identified ranging from 0.8 to 1.9 cm in greatest dimension. Two lymph node candidates submitted in block G1, two candidates in block G2, and one candidate each in blocks G3 and G4.

H. "Right gutter peritoneum", received fresh and placed in formalin is a 3.5 x 3 x 0.3 cm fragment of red-yellow fibroadipose tissue. The tissue is sectioned to reveal an unremarkable cut surface, and representative sections are submitted in block H1.

I. "Omentum", received fresh and placed in formalin is a 33 x 17 x 1 cm sheet of yellow-pink adipose tissue. The tissue appears grossly unremarkable, and no mass lesions are identified. A representative section is submitted in block I1.

J. "Right common iliac lymph node", received fresh and placed in formalin is a 1.9 x 1.8 x 0.6 cm aggregate of multiple fragments of tan-yellow fibroadipose tissue. The tissue is dissected for lymph node candidates, and one candidate 1.2 x 0.4 x 0.4 cm is identified and submitted in toto in block J1.

K. "Para-aortic lymph node", received fresh and placed in formalin is a 3.5 x 2.8 x 1.5 cm fragment of tan-pink fibroadipose tissue, which is dissected for lymph node candidates three lymph node candidates are identified ranging in size from 1.5 to 2.4 cm in greatest dimension. The two smaller candidates are submitted in block K1, and the largest candidate is bisected and submitted in block K2.

L. "Nodule of mesentery sigmoid colon", received fresh and placed in formalin is a 0.6 x 0.5 x 0.3 cm fragment of pink-tan soft tissue which is submitted in toto in block L1.

M. "Nodule mesentery appendix", received fresh and placed in formalin is a 1.2 x 1 x 0.3 cm aggregate of three similarly sized tan-white fragments of soft tissue which are submitted in toto in block M1.

A. [REDACTED]

INTRA OPERATIVE CONSULTATION:

A. "Right ovary and tube": AF1 (representative)- high-grade carcinoma, favor serous papillary

MICROSCOPIC EXAMINATION:

Microscopic examination is performed.

ATHOLOGIC STAGE:

PROCEDURE: Hysterosalpingo-oophorectomy and node dissection

[page 3 of 4]
PATHOLOGIC STAGE (AJCC 6th Edition): pT3a pN0 pMX

NOTE: Information on pathology stage and the operative procedure is transmitted to this Institution's Cancer Registry as required for accreditation by the [REDACTED] stage is based solely upon the current tissue specimen being evaluated, and does not incorporate information on any specimens submitted separately to our Cytology section, past pathology information, imaging studies, or clinical or operative findings. Pathology stage is only a component to be considered in determining the clinical stage, and should not be confused with nor substituted for it. The exact operative procedure is available in the surgeon's operative report.

DIAGNOSIS:

A. "RIGHT OVARY AND TUBE (AF1)":

RIGHT OVARY:

TYPE: PAPILLARY SEROUS ADENOCARCINOMA

FIGO GRADE: 3

TUMOR SIZE: 13 X 6.9 X 6.5 CM.

WEIGHT: 352 GRAMS

SEROSA: POSITIVE FOR TUMOR

RIGHT FALLOPIAN TUBE: POSITIVE FOR SEROUS ADENOCARCINOMA

B. "RIGHT ROUND LIGAMENT":

REACTIVE MESOTHELIUM, HEMORRHAGE, AND INFLAMMATION.
NEGATIVE FOR CARCINOMA.

C. "LEFT TUBE AND OVARY":

FALLOPIAN TUBE AND OVARY, NEGATIVE FOR CARCINOMA.

D. "CERVIX AND UTERUS AND POSTERIOR VAGINAL PERINEUM":

UTERUS, 105 GRAMS

ENDOMETRIUM: INACTIVE

MYOMETRIUM: ADENOMYOSIS AND LEIOMYOMATA

CERVIX: MUCOSA NEGATIVE FOR TUMOR, WITH ADVENTITIAL SEROUS
ADENOCARCINOMA, SEE COMMENT.

SEROSA: POSITIVE FOR SEROUS ADENOCARCINOMA (LOWER UTERINE SEGMENT,
ENDOCERVIX, AND ECTOCERVICAL PORTION OF UTERUS)

SPECIMEN MARGINS: NEGATIVE FOR TUMOR

E. "POSTERIOR VAGINAL PERITONEUM":

POSITIVE FOR SEROUS ADENOCARCINOMA, MAXIMUM TUMOR SIZE 6 MM

F. "RIGHT IP LIGAMENT":

NEGATIVE FOR CARCINOMA.

G. "RIGHT PELVIC LYMPH NODE" (DISSECTION):

SIX LYMPH NODES, NEGATIVE FOR CARCINOMA (0/6).

H. "RIGHT GUTTER PERITONEUM":

REACTIVE MESOTHELIUM, HEMORRHAGE, AND INFLAMMATION
NEGATIVE FOR CARCINOMA.

[page 4 of 4]
TCGA-29-1778

I. "OMENTUM" (PARTIAL RESECTION):

NEGATIVE FOR CARCINOMA.

J. "RIGHT COMMON ILIAC LYMPH NODE":

ONE LYMPH NODE, NEGATIVE FOR CARCINOMA (0/1).

K. "PARAAORTIC LYMPH NODE":

THREE LYMPH NODES NEGATIVE FOR CARCINOMA (0/3).

L. "NODULE OF MESENTERY SIGMOID COLON":

POSITIVE FOR SEROUS ADENOCARCINOMA
MAXIMUM TUMOR SIZE 8 MM

M. "NODULE OF MESENTERY APPENDIX":

POSITIVE FOR SEROUS ADENOCARCINOMA.
MAXIMUM TUMOR SIZE 1.2 CM

COMMENT: Immunostains of the tumor in part A are positive for CK7, Berp4, and WT1, are focally positive for CA125, and are negative for CK20, CDX2, and calretinin. As described above, in the hysterectomy specimen, adjacent to the endocervical canal is a externally based 2.5 cm area of serous adenocarcinoma. This involves the external portions of cervix, endocervix and lower uterine segment, but cervical and vaginal epithelial margins are negative for tumor.

In summary, the above findings are most consistent with a primary serous adenocarcinoma of the right ovary.

I certify that I personally conducted the diagnostic evaluation of the above specimen(s) and have rendered the above diagnosis(es).

Performed by:

Source: NCI Genomic Data Commons file 00bbabc5-0121-4107-90db-bd739202e2f5 (TCGA-29-1778.439A81DD-DC54-49E5-942C-4AA8D0BE8701.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).